Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A3BL, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A3BL-01A (Primary Tumor).

[page 1 of 2]
Surg Path Final Report

* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status:
Result Title: Auth (Verified)
Verified By: Surnina
Encounter Info:

* Final Report *

Final Diagnosis (Verified)

Right lobe of thyroid, excision, with intraoperative consultation:

Papillary carcinoma, follicular variant.

Carcinoma measures 1.2 cm in greatest dimension.

Carcinoma is encapsulated, and focal invasion of tumor into the capsule is noted.

No definitive lymphovascular invasion identified.

Negative resection margins.

"Isthmus margin of right thyroid":

Benign thyroid tissue.

AJCC pathologic stage: T1,NX.

Signature Line

(Electronically signed by)
Verified on:

ICD-0-3

Path: carcinoma, papillary, follicular variant 8340/3
CQCF: carcinoma, papillary, thyroid 8260/3 — no 11/10/11
Site: thyroid, NOS C73.9 no 10/24/11

Printed by:
Printed on:

[page 2 of 2]
Surg Path Final Report

* Final Report *

Operating Room Consultation (Verified)

History: Papillary thyroid carcinoma.

"Right lobe of thyroid" – 5.7 x 2.8 x 1.5 cm lobe of thyroid inked black. Firm white-tan nodule measuring 1.3 cm noted. Portion of nodule and portion of normal thyroid given to rule out study protocol.

Clinical Information (Verified)

Papillary cancer of thyroid.

Gross Description (Verified)

"A, ORCA." The specimen consists of a 5.7 x 2.8 x 1.5 cm previously sectioned lobe of thyroid. The specimen has previously been inked black. Previous sectioning reveals a 1.3 x 1.5 cm firm, white-tan nodule. This grossly appears to come to within 0.3 cm of the inked capsular margin. This comprises approximately 40% to 45% of the entire specimen. The remaining cut surface is red-tan and waxy. "A1-A3," white-tan, firm nodule; "A4-A5," random sections remaining thyroid, representative.

"B, Isthmus margin of right thyroid." The specimen consists of a 1.5 x 0.7 x 0.5 cm pink-tan, focally charred soft fragment, inked black. "B," fragments, all.

Signature Line

Completed Action List:

- * Order by
- * VERIFY by
- * Order by

Printed by:
Printed on:

Source: NCI Genomic Data Commons file e3f1d495-e84a-4fa5-b4a2-6643b0057198 (TCGA-FY-A3BL.410839D6-B990-415C-A2C8-2AAC60C02E9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).